Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5LA, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5LA-01A (Primary Tumor).

ICD-O-3

Carcinoma, adrenal cortical
8370/3

Site Adrenal Gland cortex
C74.2

Procedure: adrenalectomy

Gross description: 8 x 7 x 7cm, 212g

2/6/13

Reference Pathology only:

Diagnosis: adrenocortical carcinoma, KI67 1%; final diagnosis adrenocortical carcinoma, initial diagnosis adenoma, mitotic rate <1 per 10 hpf

Weiss score: 5

Hough score: 3.37

Van Slooten score: 17.8

ICDAA Discrepancy		

Source: NCI Genomic Data Commons file b5055e03-defc-4b36-a000-91ee69cba1a5 (TCGA-OR-A5LA.68F5B84D-8967-4A77-B5D9-65526AB9FFBB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).